Gene-level copy-number profile of tumor specimen TCGA-L5-A8NF-01A from TCGA case TCGA-L5-A8NF, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: GX; Age at diagnosis: 57.9 years (21,134 days).
Specimen TCGA-L5-A8NF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.7775fca8-b354-4e60-97f1-aeec0cdc3c2c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NF-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6f173097-00ff-4ea6-8cbe-61b1d722fd85

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 249; copy number 2: 8,464; copy number 3: 20,666; copy number 4: 18,660; copy number 5: 5,915; copy number 6: 3,773; copy number 7: 168; copy number 8: 901; copy number 9: 12; copy number 10: 210; copy number 12: 10; copy number 13: 276; copy number 15: 175; copy number 16: 107; copy number 17: 38; copy number 19: 64; copy number 20: 3; copy number 23: 4; copy number 25: 22; copy number 29: 46; copy number 31: 20; copy number 32: 2; copy number 43: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NF-01A-11D-A37B-01): tumor purity 0.79, ploidy 3.67, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr7:110,662,644–111,562,517, 1 gene (within-gene range 0–2): IMMP2L.
- chr7:111,091,006–111,125,454, 1 gene: LRRN3.
- chr16:78,534,374–78,796,362, 3 genes: AC046158.2, AC046158.3, AC009141.1.
- chr20:15,280,764–15,280,873, 1 gene: RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,015 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:156,585,979–159,777,828, 56 genes, copy number 16: AC096736.3, LINC02272, AC096736.2, AC096736.1, PDGFC, AC092608.1, AC092608.3, AC092608.2, AC093325.1, RPPH1-3P, Y_RNA, GLRB, RNU6-582P, GRIA2, AC112240.1, AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233.
- chr4:162,022,733–163,166,890, 9 genes, copy number 15 (within-gene range 5–15): AC023136.1, MTHFD2P4, TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1.
- chr7:78,017,055–79,453,667, 1 gene, copy number 17 (within-gene range 4–17): MAGI2.
- chr7:78,347,142–103,344,830, 463 genes, copy number 13–29 (within-gene range 4–29) (broad region; genes not listed).
- chr11:66,330,241–71,252,577, 186 genes, copy number 10–19 (broad region; genes not listed).
- chr11:71,856,277–74,738,796, 116 genes, copy number 13–15 (within-gene range 3–15) (broad region; genes not listed).
- chr11:75,099,172–75,243,704, 6 genes, copy number 15: AP001972.4, SLCO2B1, OR2AT1P, AP001972.3, ZDHHC20P3, TPBGL.
- chr11:75,260,127–75,265,170, 3 genes, copy number 15: AP001972.1, AP001972.5, AP001972.2.
- chr11:75,586,918–75,669,120, 1 gene, copy number 9 (within-gene range 4–9): MAP6.
- chr11:75,635,883–75,815,406, 9 genes, copy number 9: AP001922.2, AP001922.4, MOGAT2, RN7SL786P, AP001922.1, DGAT2, AP001922.3, AP003031.1, UVRAG-DT.
- chr11:75,835,215–75,837,645, 2 genes, copy number 9: Y_RNA, Y_RNA.
- chr12:45,014,672–45,103,107, 4 genes, copy number 23 (within-gene range 7–23): DBX2, AC008127.1, RACGAP1P1, SSBL3P.
- chr12:65,278,643–65,491,430, 1 gene, copy number 31 (within-gene range 5–31): MSRB3.
- chr12:65,418,731–66,170,072, 19 genes, copy number 31: KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4.
- chr12:66,347,431–67,352,039, 10 genes, copy number 19–32: GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1.
- chr12:67,571,197–67,753,817, 5 genes, copy number 15: LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1.
- chr12:67,989,445–68,234,686, 1 gene, copy number 15 (within-gene range 4–15): IFNG-AS1.
- chr12:68,143,318–68,671,901, 16 genes, copy number 15 (within-gene range 3–15): AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4.
- chr12:68,808,177–70,920,738, 44 genes, copy number 12–43 (within-gene range 3–43): MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA.
- chr18:21,650,901–24,162,211, 61 genes, copy number 10 (broad region; genes not listed).
- chr18:24,170,505–24,179,295, 2 genes, copy number 10: RNA5SP452, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
